Somatic mutation profile of tumor specimen TCGA-DJ-A2PX-01A (aliquot TCGA-DJ-A2PX-01A-11D-A18F-08) from TCGA case TCGA-DJ-A2PX, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 55.0 years (20,088 days).
Specimen TCGA-DJ-A2PX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7ddf4fb6-aefb-4ed8-9eb8-905dba3a19b6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DJ-A2PX-10A (Blood Derived Normal), aliquot TCGA-DJ-A2PX-10A-01D-A18F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/383740b8-6b01-4ae7-8f51-98a3f5105c99

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CYP11A1 | c.1538C>T p.P513L | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV51434490; called by muse, mutect2, varscan2
- HEPACAM2 | c.1307G>T p.C436F (on ENST00000394468 / NM_001039372.4; = p.C424F on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT tolerated (0.72); PolyPhen benign (0.012); catalogued as rs1252439199, COSV59062922; called by muse, mutect2, varscan2
- RAD51AP2 | c.1229G>A p.C410Y | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs754022293, COSV67589026; called by muse, mutect2, varscan2
